Somatic mutation profile of tumor specimen TCGA-BR-8078-01A (aliquot TCGA-BR-8078-01A-11D-2340-08) from TCGA case TCGA-BR-8078, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.8 years (25,861 days).
Specimen TCGA-BR-8078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9964d58b-eda6-4854-9ee9-4d16a602a1d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8078-10A (Blood Derived Normal), aliquot TCGA-BR-8078-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f364bcd8-8bd1-47e8-a9a5-3dbc0b603f0b

The open-access MAF lists 1,884 somatic variants for this specimen: 1,477 protein-altering or splice-affecting, 362 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 890, Frame Shift Del 423, Silent 362, Frame Shift Ins 71, Nonsense Mutation 37, Splice Site 23, Intron 20, In Frame Del 15, Splice Region 13, RNA 9, 5'Flank 6, 3'UTR 5.

Variants (750 of 1,884; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.8940dup p.E2981Rfs*37 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | catalogued as rs80359732; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.9253dup p.T3085Nfs*26 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs80359752; ClinVar: pathogenic; called by mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 29/156 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918485, CM002958, COSV61316452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HNF1B | c.1561dup p.Q521Pfs*30 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 21/32 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- RPL10 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1557184925, COSV50010858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.6172del p.S2058Lfs*19 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs1214399996, CD056852, CD1111485; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC12A3 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775931992, CM014400, COSV52635778; ClinVar: pathogenic; called by muse, mutect2
- TPP1 | c.1449del p.I484Sfs*4 | Frame Shift Del (DEL) | VAF 40/129 reads (31%) | catalogued as rs1057516264; ClinVar: likely pathogenic; called by mutect2, varscan2
- A4GALT | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs770640796, COSV50745460; called by muse, mutect2, varscan2
- ABCC10 | c.1328G>A p.R443H (on ENST00000372530 / NM_001198934.2; = p.R400H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758290484, COSV55092100; called by muse, mutect2, varscan2
- ABCC6 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756910757, CM091245, COSV52743066; called by muse, mutect2
- ABCF2 | c.1844A>C p.Q615P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV55185362; called by muse, mutect2, varscan2
- ABCF3 | c.680G>C p.S227T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV53049566; called by muse, mutect2, varscan2
- ABI3BP | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52545973; called by muse, mutect2, varscan2
- AC008397.2 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53206219, COSV53208687; called by muse, mutect2, varscan2
- ACAP2 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1309850569, COSV58754378; called by muse, mutect2, varscan2
- ACE | c.2913-1G>A p.X971_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52005409; called by muse, mutect2, varscan2
- ACOX3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs142830697; called by muse, mutect2, varscan2
- ACTL6A | c.269del p.N90Mfs*47 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs1560010257; called by mutect2, pindel, varscan2
- ACTN3 | c.2377G>A p.G793S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59750041; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/80 reads (70%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV55985523; called by muse, mutect2, varscan2
- ADAMTS16 | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs200531128, COSV57001217; called by muse, mutect2
- ADAMTS5 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53183025; called by muse, mutect2
- ADAMTS9 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as rs1188539097, COSV55787080; called by muse, mutect2, varscan2
- ADAMTSL4 | c.679del p.Q227Kfs*5 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs768188442; called by mutect2, pindel, varscan2
- ADCY1 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52031923; called by muse, mutect2, varscan2
- ADCY7 | c.1477del p.A493Rfs*14 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs1259233981; called by mutect2, pindel, varscan2
- ADCY8 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV53920279; called by muse, mutect2, varscan2
- ADGRB2 | c.2299A>C p.S767R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57077053; called by muse, mutect2, varscan2
- ADGRB2 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV57077066; called by muse, mutect2, varscan2
- ADGRD1 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55452638; called by muse, varscan2
- ADGRE5 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372889912; called by muse, mutect2, varscan2
- ADGRF1 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1030553158, COSV51946951; called by muse, mutect2, varscan2
- ADGRG4 | c.1027del p.T343Rfs*138 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | catalogued as rs765131609; called by mutect2, pindel, varscan2
- ADGRL1 | c.2288T>G p.V763G (on ENST00000340736 / NM_001008701.3; = p.V758G on NM_014921.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61566000; called by muse, mutect2, varscan2
- ADGRL3 | c.2911C>T p.R971W (on ENST00000506720 / NM_001322402.2; = p.R903W on NM_015236.6) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747197228, COSV72230097; called by muse, mutect2
- ADGRV1 | c.6170C>T p.T2057I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV67991940; called by muse, mutect2, varscan2
- AFF3 | c.3484G>A p.V1162I | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs776241053, COSV57865899; called by muse, mutect2, varscan2
- AFTPH | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775045835, COSV53220549; called by muse, mutect2, varscan2
- AGAP1 | c.2315C>T p.A772V (on ENST00000304032 / NM_001037131.3; = p.A719V on NM_014914.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1349751380, COSV58335314; called by muse, mutect2, varscan2
- AGTPBP1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as rs1433230227, COSV61274122; called by muse, varscan2
- AHNAK2 | c.15299C>T p.A5100V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV60924538; called by muse, mutect2, varscan2
- AIMP2 | c.863T>G p.I288S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52241966; called by muse, mutect2, varscan2
- AJUBA | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs768367910, COSV52986243; called by muse, mutect2, varscan2
- AKR1B10 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62056172; called by muse, mutect2, varscan2
- ALDH1A1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs762664992, COSV52793255; called by muse, mutect2, varscan2
- ALDH2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs140919090; called by muse, mutect2, varscan2
- ALDH3B1 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV50290166; called by muse, mutect2, varscan2
- ALDH8A1 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV55643557; called by muse, mutect2, varscan2
- ALG9 | c.1742T>A p.V581D (on ENST00000614444 / NM_001352418.1; = p.V588D on NM_024740.2) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV67645234; called by muse, varscan2
- ALKBH5 | c.1026G>T p.M342I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV67687232; called by muse, mutect2, varscan2
- ALOX5 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151270582, COSV65553149; called by muse, mutect2, varscan2
- ALPK3 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766905744, COSV51937501; called by muse, mutect2
- AMD1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1463233722, COSV64387596; called by muse, mutect2, varscan2
- AMDHD2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV53551868; called by muse, mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs868780344; called by mutect2, varscan2
- ANO7 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs756508348, COSV51476257; called by muse, mutect2, varscan2
- ANOS1 | c.622T>A p.F208I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52924085; called by muse, mutect2, varscan2
- ANP32A | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51189817; called by muse, mutect2, varscan2
- ANXA10 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.278); catalogued as rs865912081, COSV63738659; called by muse, mutect2, varscan2
- AP1B1 | c.2518A>G p.K840E | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.374); catalogued as COSV58021588; called by muse, mutect2, varscan2
- APBA1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1279410417, COSV55233793; called by muse, mutect2, varscan2
- APBB1 | c.849del p.G284Afs*48 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as COSV54976931; called by mutect2, pindel, varscan2
- APOB | c.11252T>C p.V3751A | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51946131; called by muse, mutect2, varscan2
- APOBR | c.1217A>G p.E406G (on ENST00000431282; = p.E415G on NM_018690.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs776596914, COSV60492909; called by muse, mutect2, varscan2
- ARAP3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554504713, COSV53349117; called by muse, mutect2, varscan2
- ARHGAP12 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60965304; called by muse, mutect2, varscan2
- ARHGAP30 | c.2401G>T p.G801* | Nonsense Mutation (SNP) | VAF 51/182 reads (28%) | catalogued as COSV63518285; called by muse, mutect2, varscan2
- ARHGAP39 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52774275; called by muse, mutect2
- ARHGEF17 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs921404723, COSV55235728; called by muse, mutect2, varscan2
- ARHGEF17 | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55235044; called by muse, mutect2, varscan2
- ARHGEF18 | c.1729C>T p.R577W (on ENST00000359920 / NM_001130955.2; = p.R473W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs532220710, COSV60472473; called by muse, mutect2, varscan2
- ARHGEF3 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV56330512; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 22/104 reads (21%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID2 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57608182; called by muse, mutect2, varscan2
- ARID5A | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs544764108, COSV62591108, COSV62591518; called by muse, mutect2, varscan2
- ARL8A | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV55343838; called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs765705848, COSV63437562; called by muse, mutect2, varscan2
- ARRDC4 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs1567194452, COSV51419186; called by muse, mutect2, varscan2
- ARSL | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV66965610; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASB10 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV51999094; called by muse, mutect2, varscan2
- ASH1L | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV64211760; called by muse, mutect2, varscan2
- ATP13A2 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs150748722, CM098009; called by mutect2, varscan2
- ATP13A3 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55467992; called by muse, mutect2, varscan2
- ATP2B3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54856697; called by muse, mutect2, varscan2
- ATP5F1B | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV51641056; called by muse, mutect2, varscan2
- ATP6V1D | c.309T>C p.G103= | Splice Region (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53600237; called by muse, mutect2, varscan2
- ATP8B3 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs199577759, COSV59540516; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs1554873914; called by mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- ATXN7L2 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs754489154, COSV63992666; called by muse, mutect2, varscan2
- AUNIP | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65353030, COSV65353427; called by muse, mutect2, varscan2
- AXIN2 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747647668, COSV61059552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR3 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV53077735; called by muse, mutect2, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV51655892; called by pindel, varscan2
- BCL7A | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs756158547, COSV55850288; called by muse, mutect2, varscan2
- BFSP1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746995142, COSV64899273; called by muse, mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BIRC5 | c.23del p.P8Lfs*67 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV104399585; called by mutect2, pindel, varscan2
- BMP1 | c.2861T>G p.V954G | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV60533478; called by muse, mutect2, varscan2
- BMP6 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753918736, COSV51670383; called by muse, varscan2
- BMP6 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1333511155, COSV51670388; called by muse, varscan2
- BMPR1B | c.76del p.R26Vfs*31 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | catalogued as COSV99215447; called by mutect2, pindel, varscan2
- BMPR2 | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs746338253, COSV101001598; called by muse, mutect2, varscan2
- BOC | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1338102608, COSV56355771; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRD1 | c.2833G>A p.A945T (on ENST00000216267 / NM_001349940.1; = p.A1076T on NM_001304808.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV53460278; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 18/24 reads (75%) | catalogued as rs763134487; called by mutect2, varscan2
- BRDT | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.46); catalogued as COSV62866490; called by muse, mutect2, varscan2
- BRI3BP | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58296987; called by muse, mutect2, varscan2
- BRPF3 | c.1814T>C p.L605P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60208936; called by muse, mutect2, varscan2
- BRSK1 | c.794T>C p.M265T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV58665041, COSV58668782; called by muse, mutect2, varscan2
- BTBD7 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV54138188; called by muse, mutect2, varscan2
- C14orf39 | c.1057A>G p.R353G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58783998; called by muse, mutect2, varscan2
- C19orf57 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.563); catalogued as COSV60969641; called by muse, mutect2, varscan2
- C1D | c.359dup p.N120Kfs*17 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs776000138; called by mutect2, pindel, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 44/94 reads (47%) | catalogued as rs781818365; called by mutect2, varscan2
- C1orf131 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV59642857; called by muse, mutect2, varscan2
- C20orf194 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.509); catalogued as COSV52693736; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs201447915; called by mutect2, pindel*
- C7orf25 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63274069; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs747591930; called by mutect2, varscan2
- CACNA1A | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764554276, COSV64207176; called by muse, mutect2, varscan2
- CACNG5 | c.476A>C p.E159A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV50057572; called by muse, mutect2, varscan2
- CADM3 | c.452A>G p.N151S (on ENST00000368125 / NM_001127173.3; = p.N185S on NM_021189.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV63686709; called by muse, mutect2, varscan2
- CALHM2 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.059); catalogued as COSV53297315; called by muse, mutect2, varscan2
- CAMTA1 | c.4691A>G p.Y1564C | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57918408; called by muse, mutect2, varscan2
- CAND2 | c.1033G>A p.D345N (on ENST00000456430 / NM_001162499.2; = p.D252N on NM_012298.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs757397927, COSV55992875; called by muse, mutect2, varscan2
- CANT1 | c.556del p.V186Sfs*14 | Frame Shift Del (DEL) | VAF 55/198 reads (28%) | catalogued as COSV56604923; called by mutect2, varscan2
- CAPN10 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as rs759430755, COSV54378591; called by mutect2, varscan2
- CAPN5 | c.1489G>A p.V497I (on ENST00000456580; = p.V457I on NM_004055.5) | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as rs553160472, COSV53690277; called by muse, mutect2, varscan2
- CARNS1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs776913935, COSV57049877; called by muse, mutect2, varscan2
- CASP4 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs138280041; called by muse, mutect2, varscan2
- CASP4 | c.128del p.K43Rfs*37 | Frame Shift Del (DEL) | VAF 35/127 reads (28%) | catalogued as rs772291949; called by mutect2, pindel, varscan2
- CASS4 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.478); catalogued as rs146715351, COSV64385655; called by muse, mutect2, varscan2
- CBLN1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54654766; called by muse, mutect2, varscan2
- CBLN2 | c.629del p.G210Afs*21 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | catalogued as COSV54052857; called by mutect2, pindel, varscan2
- CCDC14 | c.1145del p.N382Mfs*2 (on ENST00000488653; = p.N334Mfs*2 on NM_022757.5) | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as rs1559796959; called by mutect2, pindel, varscan2
- CCDC170 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs1426711051, COSV53344273; called by muse, mutect2, varscan2
- CCDC61 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99151519; called by muse, mutect2
- CCM2 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV51850454; called by muse, mutect2, varscan2
- CCM2L | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52951836; called by muse, mutect2, varscan2
- CCN4 | c.488dup p.R164Afs*18 | Frame Shift Ins (INS) | VAF 16/76 reads (21%) | catalogued as rs773550125; called by mutect2, pindel, varscan2
- CCNC | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58334691; called by muse, mutect2, varscan2
- CCNL2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68766984; called by muse, mutect2, varscan2
- CCS | c.285del p.P96Lfs*13 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs759691599; called by mutect2, pindel, varscan2
- CCSER2 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56509644, COSV56513993; called by muse, mutect2, varscan2
- CD300C | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763827378, COSV100423289, COSV58171102; called by muse, mutect2, varscan2
- CD55 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV58577690; called by muse, mutect2, varscan2
- CDC14A | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781410426, COSV60561571; called by muse, mutect2, varscan2
- CDC37 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs755464378, COSV55769371; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH10 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100049639, COSV52591372; called by muse, mutect2, varscan2
- CDH9 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV50371261; called by muse, mutect2, varscan2
- CDYL2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV73654569; called by muse, mutect2, varscan2
- CELF1 | c.1390G>A p.G464S (on ENST00000358597 / NM_001376422.1; = p.G460S on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs774921038, COSV60114324; called by muse, mutect2, varscan2
- CELSR1 | c.7772G>A p.G2591D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53096386; called by muse, mutect2, varscan2
- CELSR2 | c.2801G>A p.S934N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV54777094; called by muse, mutect2
- CELSR3 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as rs375268987; called by muse, mutect2, varscan2
- CELSR3 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV51000712; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP97 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.691); catalogued as COSV59126691; called by muse, mutect2, varscan2
- CFAP221 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV54660672, COSV54664035; called by muse, varscan2
- CFAP46 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV63953323; called by muse, mutect2, varscan2
- CFAP53 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV68352559; called by muse, mutect2, varscan2
- CFAP58 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as rs761844995; called by mutect2, pindel, varscan2
- CFAP65 | c.3846+2T>C p.X1282_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | catalogued as COSV58564578; called by muse, mutect2, varscan2
- CHD7 | c.8353G>A p.A2785T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs935815422, COSV71113304; called by muse, mutect2, varscan2
- CHIA | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs769844294, COSV58475679; called by muse, mutect2, varscan2
- CHMP4C | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51928270; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 34/66 reads (52%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255269289, COSV57323095; called by muse, mutect2, varscan2
- CIBAR2 | c.547dup p.C183Lfs*2 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs768027256; called by mutect2, varscan2
- CIT | c.2645C>T p.S882F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV55878135; called by muse, mutect2, varscan2
- CLCNKB | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65161455; called by muse, mutect2, varscan2
- CLDN17 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.773); catalogued as COSV54524087; called by muse, mutect2, varscan2
- CLEC3B | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV56110272, COSV99944558; called by muse, mutect2, varscan2
- CLIP1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1200045691, COSV56806220; called by muse, mutect2, varscan2
- CLIP2 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs373377941; called by muse, mutect2, varscan2
- CLUH | c.976del p.Q326Rfs*80 (on ENST00000435359; = p.Q364Rfs*80 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1418382371; called by mutect2, pindel, varscan2
- CMYA5 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1176298481, COSV71408382; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNOT2 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57505558; called by muse, mutect2, varscan2
- CNTN4 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs896789494, COSV61876875, COSV61878084; called by muse, mutect2, varscan2
- COG3 | c.2294T>C p.L765S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.386); catalogued as COSV63074324; called by muse, mutect2, varscan2
- COIL | c.587dup p.A197Gfs*2 | Frame Shift Ins (INS) | VAF 28/103 reads (27%) | catalogued as rs748995811; called by mutect2, varscan2
- COL11A2 | c.4979G>A p.R1660H (on ENST00000341947 / NM_080680.3; = p.R1553H on NM_080679.2) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs202191908, COSV59498319; called by muse, mutect2, varscan2
- COL1A1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs533106127, COSV56807004; called by muse, mutect2, varscan2
- COL27A1 | c.4047C>T p.G1349= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61929491; called by muse, mutect2, varscan2
- COL27A1 | c.5219T>C p.V1740A | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs760148638, COSV61929496; called by muse, mutect2, varscan2
- COL6A3 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs200825417, COSV55101667; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- COLGALT2 | c.767del p.P256Hfs*41 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as COSV100730886; called by mutect2, pindel, varscan2
- COPS5 | c.251A>T p.K84M | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63474725; called by muse, mutect2, varscan2
- COX8C | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV56402528; called by muse, mutect2, varscan2
- CPB1 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.368); catalogued as COSV51575754; called by muse, mutect2, varscan2
- CPLX1 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58377007; called by muse, mutect2, varscan2
- CPNE4 | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.07); catalogued as COSV70198079; called by muse, mutect2, varscan2
- CPSF2 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54099996; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRBN | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.034); catalogued as rs374934479; called by muse, mutect2, varscan2
- CRCP | c.248A>G p.K83R | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58536332; called by muse, mutect2, varscan2
- CRLF1 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV66505169; called by muse, mutect2, varscan2
- CRTAC1 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769753665, COSV54003405; called by muse, mutect2, varscan2
- CRTC3 | c.1666A>G p.S556G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV51599156; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs762650691; called by mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs1559328208, COSV53679868; called by mutect2, pindel, varscan2
- CSF3R | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs150616658, COSV58963124; called by muse, mutect2, varscan2
- CSMD1 | c.9988G>A p.V3330M (on ENST00000520002; = p.V3329M on NM_033225.6) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59360088; called by muse, mutect2, varscan2
- CSMD1 | c.4008G>T p.W1336C (on ENST00000520002; = p.W1335C on NM_033225.6) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59360112, COSV59361642; called by muse, mutect2, varscan2
- CSMD2 | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1260407987, COSV53891820; called by muse, mutect2, varscan2
- CSMD2 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs779556893, COSV53907596, COSV53925434; called by muse, mutect2
- CSTF2T | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as rs764346235, COSV58657222; called by muse, mutect2, varscan2
- CTAG2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs782359239, COSV55996248; called by muse, mutect2, varscan2
- CTAGE1 | c.2216T>C p.F739S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754360939, COSV66944194; called by muse, mutect2, varscan2
- CTCFL | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762680387, COSV54777515; called by muse, mutect2, varscan2
- CTNND2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.51); catalogued as COSV58912085; called by muse, mutect2
- CTR9 | c.2045A>T p.D682V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV63729302; called by muse, mutect2, varscan2
- CUL3 | c.1358del p.N453Tfs*2 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs1366667901; called by mutect2, pindel, varscan2
- CUL3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.821); catalogued as COSV100024558, COSV52363756; called by muse, mutect2, varscan2
- CUL9 | c.7051G>A p.V2351M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458331166, COSV52736350; called by muse, mutect2
- CYBB | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782094658, COSV66084889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYLD | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61096539; called by muse, mutect2, varscan2
- CYP11B1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372378491; called by mutect2, varscan2
- CYP2E1 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV53314632; called by muse, mutect2, varscan2
- CYP7B1 | c.314dup p.N105Kfs*3 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs747514385; called by mutect2, pindel, varscan2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs753942205; called by mutect2, pindel, varscan2
- DCAF12L2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770854200, COSV63580452, COSV63582250; called by muse, mutect2, varscan2
- DCAF4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.187); catalogued as rs370247731; called by muse, mutect2, varscan2
- DCAF4L1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV60786317; called by muse, mutect2
- DCAF8 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs376611740, COSV58785320; called by muse, mutect2, varscan2
- DCAF8L1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.219); catalogued as COSV101491451, COSV71595444; called by muse, mutect2, varscan2
- DCDC1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs374157559; called by muse, mutect2, varscan2
- DCTN2 | c.599del p.P200Qfs*32 (on ENST00000548249 / NM_001261413.2; = p.P205Qfs*32 on NM_006400.4) | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs745744034; called by mutect2, pindel, varscan2
- DDI1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs778814876, COSV56374301; called by muse, mutect2, varscan2
- DDIT4L | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV56767878; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX21 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs766854373, COSV62555106; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 9/24 reads (38%) | catalogued as rs755280697; called by mutect2, pindel, varscan2
- DDX54 | c.2174G>T p.R725M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as COSV58375295; called by muse, mutect2, varscan2
- DDX55 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs916500018, COSV53017053; called by muse, mutect2, varscan2
- DEAF1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1357548937, COSV58608645; called by muse, mutect2, varscan2
- DENND1C | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs749544483, COSV57567958; called by muse, mutect2, varscan2
- DEPDC5 | c.2905A>G p.M969V (on ENST00000400246; = p.M1038V on NM_014662.5) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as COSV56705723; called by muse, mutect2, varscan2
- DGAT1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV60048930; called by muse, mutect2
- DGCR8 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs201293912, COSV61226934; called by muse, mutect2, varscan2
- DHCR7 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs765908713, COSV62796156; called by muse, mutect2, varscan2
- DHX38 | c.1567_1569del p.K523del | In Frame Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs745391363; called by pindel, varscan2
- DIAPH1 | c.2308A>C p.K770Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53879146; called by muse, varscan2
- DIAPH1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754730261, COSV53884826; called by muse, mutect2, varscan2
- DIAPH2 | c.1727C>A p.P576H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV61285001; called by muse, mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs762377755; called by mutect2, varscan2
- DLC1 | c.2679C>A p.D893E (on ENST00000276297 / NM_001348081.2; = p.D456E on NM_006094.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1395104994, COSV52319376; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | catalogued as COSV52307798; called by mutect2, pindel, varscan2
- DLEC1 | c.4559T>C p.L1520P | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57178019; called by muse, mutect2, varscan2
- DLGAP2 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.299); catalogued as rs545241585, COSV101422136, COSV70102290; called by muse, mutect2
- DLL3 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52694862; called by muse, mutect2, varscan2
- DMD | c.6152G>A p.R2051Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756696562, COSV63758358; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 11/33 reads (33%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH3 | c.7957T>C p.S2653P | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54540213; called by muse, mutect2, varscan2
- DNAJB7 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV53422983; called by muse, mutect2, varscan2
- DOCK3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56538547, COSV56539664; called by muse, mutect2, varscan2
- DOCK4 | c.5722C>T p.R1908W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs766904292, COSV70241183; called by muse, varscan2
- DOCK5 | c.5411C>T p.P1804L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as rs773505640, COSV52408069; called by muse, mutect2, varscan2
- DOLPP1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59910806; called by muse, mutect2, varscan2
- DOP1A | c.2654G>T p.G885V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV52715024; called by muse, varscan2
- DPH2 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV52544521; called by muse, mutect2, varscan2
- DPY19L2 | c.451-2del p.X151_splice | Splice Site (DEL) | VAF 36/100 reads (36%) | catalogued as rs202064990, COSV60543692; called by pindel, varscan2
- DROSHA | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs546365755, COSV60777010; called by muse, mutect2, varscan2
- DSTYK | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65687736; called by muse, mutect2, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs758962538; called by mutect2, varscan2
- DTX3L | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755071547, COSV56144163; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV50052543; called by muse, mutect2, varscan2
- DUSP10 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV60459205; called by muse, mutect2, varscan2
- DVL3 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as rs751639591, COSV57456252, COSV57457563; called by muse, mutect2, varscan2
- DYNC1H1 | c.5410C>T p.R1804* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100795246, COSV64140301; called by muse, mutect2, varscan2
- DYRK4 | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50542733; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- DYSF | c.3605C>T p.T1202M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294912316, COSV50309860, COSV50513991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP1 | c.1783C>T p.R595* (on ENST00000347108; = p.R576* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as rs756109756, COSV61263776; called by muse, mutect2, varscan2
- DZIP1L | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs758115822, COSV59519026, COSV59520345; called by muse, varscan2
- E2F2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV62276654; called by muse, mutect2, varscan2
- EBF2 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV68779596; called by muse, mutect2, varscan2
- EEA1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV59288565; called by muse, mutect2, varscan2
- EEF2KMT | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV69863661; called by muse, mutect2, varscan2
- EFCAB7 | c.1317A>C p.K439N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as COSV64315139; called by muse, mutect2, varscan2
- EGR1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53520788; called by muse, mutect2, varscan2
- EHBP1 | c.2266dup p.T756Nfs*8 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs1379721094; called by mutect2, varscan2
- EHD1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs774644717, COSV57736009; called by muse, mutect2, varscan2
- EHF | c.342C>T p.N114= | Splice Region (SNP) | VAF 41/145 reads (28%) | catalogued as rs907609906, COSV57668234, COSV57669410; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF4G3 | c.1689dup p.V564Sfs*12 | Frame Shift Ins (INS) | VAF 50/200 reads (25%) | catalogued as rs1558140642; called by mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELAVL1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs757692680, COSV60967799; called by muse, mutect2, varscan2
- ELMO1 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV60317233; called by muse, mutect2, varscan2
- ELMO2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV51685153; called by muse, mutect2, varscan2
- ELSPBP1 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV60414558; called by muse, mutect2, varscan2
- EML3 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.242); catalogued as COSV53883982; called by muse, mutect2, varscan2
- ENAH | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1390095572, COSV52871105; called by muse, mutect2, varscan2
- ENTPD3 | c.1543_1546del p.K515Gfs*48 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1191881201; called by pindel, varscan2
- EPC2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51547516; called by muse, mutect2, varscan2
- EPC2 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as rs1463279431, COSV51547529; called by muse, mutect2, varscan2
- EPHA2 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs568736295, COSV64453688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHB6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs756659047, COSV67417355, COSV67421793; called by muse, mutect2, varscan2
- EPHB6 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.937); catalogued as rs143338098, COSV63892976; called by muse, mutect2, varscan2
- EPHX2 | c.548dup p.L183Ffs*3 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs1442463502; called by mutect2, varscan2
- ERCC6L | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57821698; called by muse, mutect2, varscan2
- ERI3 | c.39del p.R14Gfs*55 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs1184349425; called by mutect2, varscan2
- ERICH3 | c.2486G>A p.R829K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs748071177, COSV58603387; called by muse, mutect2, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs753821453; called by mutect2, varscan2
- ESPN | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); catalogued as COSV64705197; called by muse, mutect2, varscan2
- EVX2 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57964562; called by muse, mutect2, varscan2
- EXD1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763820609, COSV59253155; called by muse, varscan2
- EXOC4 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs759701016, COSV54113573, COSV54116589; called by muse, mutect2, varscan2
- EXOC7 | c.1233G>T p.E411D (on ENST00000335146 / NM_001145297.4; = p.E329D on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV58743784; called by muse, mutect2, varscan2
- EXOSC8 | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53509778; called by muse, mutect2, varscan2
- EXT1 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV65483143; called by muse, mutect2, varscan2
- EYA1 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as COSV58169946; called by muse, mutect2, varscan2
- EYS | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60995828; called by muse, mutect2
- FADS3 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs767888295, COSV53878336; called by muse, mutect2, varscan2
- FAM110B | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64067084; called by muse, varscan2
- FAM110B | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs556320056, COSV64067091; called by muse, varscan2
- FAM120B | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs754445368, COSV53006914; called by muse, mutect2, varscan2
- FAM124B | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54739449; called by muse, mutect2, varscan2
- FAM126B | c.774A>C p.E258D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV53774306; called by muse, mutect2, varscan2
- FAM135B | c.3746C>A p.P1249H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52743968; called by muse, mutect2, varscan2
- FAM13B | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs375616241; called by muse, mutect2, varscan2
- FAM160A2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56413575; called by muse, mutect2, varscan2
- FAM162B | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63920632, COSV63920791; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM241B | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV64768695; called by muse, varscan2
- FAM47B | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs368344355, COSV61455944, COSV99051670; called by muse, mutect2, varscan2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FANCM | c.3190del p.S1064Vfs*31 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs778191984; called by mutect2, pindel, varscan2
- FARSA | c.832_834del p.F278del | In Frame Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs764095148; called by pindel, varscan2
- FAT2 | c.9429C>T p.G3143= | Splice Region (SNP) | VAF 29/73 reads (40%) | catalogued as rs1281542562, COSV55823803; called by muse, mutect2, varscan2
- FAT3 | c.10702G>T p.G3568W | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53153564; called by muse, mutect2, varscan2
- FAT4 | c.10559T>C p.M3520T | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58700777; called by muse, mutect2, varscan2
- FBN1 | c.2066A>C p.E689A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV57325923; called by muse, mutect2, varscan2
- FBN3 | c.4693G>A p.D1565N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs767659218, COSV54457780; called by muse, mutect2, varscan2
- FBXO10 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs182563461, COSV52834675; called by muse, mutect2, varscan2
- FBXO10 | c.550T>G p.F184V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99447044; called by muse, mutect2, varscan2
- FBXO30 | c.2068A>G p.N690D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52791642, COSV52792596; called by muse, mutect2, varscan2
- FBXO41 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs746483059, COSV54587810; called by muse, mutect2, varscan2
- FBXW9 | c.548G>A p.R183Q (on ENST00000587955; = p.R193Q on NM_032301.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774734992, COSV100790388, COSV63509485; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs747094222, COSV67548414; called by mutect2, varscan2
- FERMT3 | c.1352G>A p.G451D (on ENST00000279227 / NM_178443.3; = p.G447D on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV54182297; called by muse, mutect2, varscan2
- FETUB | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs141401279; called by muse, mutect2, varscan2
- FGD5 | c.3817C>T p.R1273W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753008473, COSV53248653; called by muse, mutect2, varscan2
- FGF13 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as rs1329913427, COSV65435070; called by muse, mutect2, varscan2
- FGF23 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1472287974, COSV52977342; called by muse, mutect2, varscan2
- FHOD3 | c.4094T>A p.I1365N (on ENST00000359247 / NM_001281739.3; = p.I1382N on NM_025135.5) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57182720; called by muse, mutect2, varscan2
- FICD | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767630290, COSV57207784; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/135 reads (27%) | catalogued as COSV58769165; called by mutect2, varscan2
- FIZ1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1246714458, COSV55608426; called by muse, mutect2, varscan2
- FKBPL | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV64322763; called by muse, mutect2, varscan2
- FLG | c.6577del p.T2193Hfs*226 | Frame Shift Del (DEL) | VAF 98/403 reads (24%) | catalogued as COSV100912393; called by pindel, varscan2
- FLNC | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57961401; called by muse, mutect2, varscan2
- FLT4 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753863393, COSV56117471; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV56098414; called by mutect2, pindel, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FOCAD | c.4909G>A p.V1637I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs755671239, COSV58093336; called by muse, mutect2, varscan2
- FOSB | c.822del p.N275Tfs*2 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as COSV62279449; called by mutect2, pindel, varscan2
- FOSL1 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV57028915; called by muse, mutect2, varscan2
- FOXG1 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV57398562; called by muse, mutect2, varscan2
- FOXJ1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs762912751, COSV53947058; called by muse, mutect2, varscan2
- FOXO3 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV59630185; called by muse, mutect2, varscan2
- FOXQ1 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs770819384, COSV57259274; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSTL5 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | catalogued as rs141917472, COSV60192986; called by muse, mutect2, varscan2
- FUT8 | c.1657T>C p.Y553H (on ENST00000360689 / NM_001371534.1; = p.Y390H on NM_004480.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61288873; called by muse, mutect2, varscan2
- FZD1 | c.794del p.G265Afs*143 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV55308793, COSV55313838; called by mutect2, varscan2
- FZD4 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV72294608; called by muse, mutect2, varscan2
- G2E3 | c.1823A>G p.K608R | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV52842079; called by muse, mutect2, varscan2
- GAB3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65820413; called by muse, mutect2, varscan2
- GABRA3 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV64803085; called by muse, mutect2, varscan2
- GALNT10 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV51731548; called by muse, mutect2, varscan2
- GALNT11 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs766807653, COSV57424702; called by muse, mutect2, varscan2
- GAPDHS | c.492_493insA p.Y165Ifs*44 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as COSV99722432; called by mutect2, pindel, varscan2
- GAPVD1 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV52926049; called by muse, mutect2, varscan2
- GAS2L2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781984212; called by muse, mutect2, varscan2
- GAS7 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV71563823; called by muse, mutect2, varscan2
- GCAT | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs768591554, COSV50649824; called by muse, mutect2, varscan2
- GDF6 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as rs765908995, COSV54626821; called by muse, mutect2
- GDF7 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55348278; called by muse, mutect2, varscan2
- GGA3 | c.1876G>C p.V626L (on ENST00000537686 / NM_138619.4; = p.V593L on NM_014001.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55458183; called by muse, mutect2, varscan2
- GGA3 | c.1100G>A p.R367Q (on ENST00000537686 / NM_138619.4; = p.R334Q on NM_014001.5) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.267); catalogued as rs369877572; called by muse, mutect2, varscan2
- GIMAP8 | c.1730A>T p.D577V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV56232995; called by muse, mutect2, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GJD4 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974846535, COSV58703059; called by muse, mutect2, varscan2
- GLB1L3 | c.1095C>A p.S365R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66282730; called by muse, mutect2, varscan2
- GLI1 | c.534+2T>C p.X178_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57365381; called by muse, mutect2, varscan2
- GLI3 | c.4175G>A p.S1392N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs773316349, COSV67892922; called by muse, mutect2, varscan2
- GLIS1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV56553704; called by muse, mutect2, varscan2
- GLIS1 | c.344del p.G115Afs*31 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV100389202; called by mutect2, pindel, varscan2
- GLRA3 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.91); catalogued as COSV56867217; called by muse, varscan2
- GLT8D2 | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV62561441, COSV62562707; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs749150409; called by mutect2, varscan2
- GMIP | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs1164997730, COSV52558769; called by muse, mutect2
- GMPR | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143277148, COSV52474638; called by muse, mutect2, varscan2
- GNB1L | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV61549303; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 40/83 reads (48%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNPTAB | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as rs1431907386, COSV68449844; called by muse, mutect2, varscan2
- GON4L | c.5842G>T p.A1948S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.037); catalogued as COSV55199858; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs370114090; called by mutect2, varscan2
- GP1BA | c.1480del p.T494Pfs*59 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as rs759573909; called by mutect2, varscan2
- GP5 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV55467981; called by muse, mutect2, varscan2
- GPAT2 | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64003770; called by muse, mutect2
- GPAT4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs746510734, COSV67840573; called by muse, mutect2, varscan2
- GPC4 | c.1204T>C p.S402P | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV63699047; called by muse, mutect2, varscan2
- GPC4 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV63699051; called by muse, mutect2, varscan2
- GPHN | c.2110C>T p.R704C (on ENST00000315266 / NM_001377519.1; = p.R737C on NM_020806.5) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1484644467, COSV59480697; called by muse, mutect2, varscan2
- GPR137C | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379956962, COSV58706299; called by muse, mutect2, varscan2
- GPR50 | c.817A>C p.N273H | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV54441622; called by muse, mutect2, varscan2
- GPR52 | c.797T>G p.V266G | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52315128; called by muse, mutect2, varscan2
- GPRIN1 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs146734819; called by muse, mutect2, varscan2
- GPRIN2 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs577851615, COSV100966444; called by muse, mutect2
- GRAMD1B | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.323); catalogued as rs757313912, COSV59208764; called by muse, mutect2, varscan2
- GRIA1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV53616738; called by muse, mutect2, varscan2
- GRIA3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.973); catalogued as COSV52074235; called by muse, mutect2, varscan2
- GRID1 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV60014607; called by muse, mutect2, varscan2
- GRIN2B | c.4031C>T p.A1344V | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.106); catalogued as rs759438353, COSV74207100; called by muse, mutect2, varscan2
- GRM1 | c.2237G>A p.C746Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51230079; called by muse, mutect2, varscan2
- GRM7 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV63159553; called by muse, mutect2, varscan2
- GRN | c.1647C>T p.G549= | Splice Region (SNP) | VAF 21/68 reads (31%) | catalogued as rs745391227, COSV50008276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSX2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.225); catalogued as COSV58843320; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as COSV54945907; called by mutect2, varscan2
- GULP1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs748933734, COSV63071461; called by muse, mutect2, varscan2
- GYS2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as rs778872253, COSV53926942; called by muse, mutect2, varscan2
- GZMH | c.340-2A>C p.X114_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV53539106; called by muse, mutect2, varscan2
- H2AC14 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100297656, COSV60798844; called by muse, mutect2, varscan2
- H2BC4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as COSV58416668, COSV58417201; called by muse, mutect2, varscan2
- HACE1 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53502066, COSV53505656; called by muse, mutect2, varscan2
- HAPLN1 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1471633820; called by mutect2, varscan2
- HAX1 | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV55178370; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCRTR2 | c.32dup p.C12Lfs*12 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs755844571; called by mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by muse, mutect2, varscan2
- HDAC7 | c.2626C>T p.P876S (on ENST00000427332; = p.P915S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs750793586, COSV50401800; called by muse, mutect2, varscan2
- HDAC7 | c.1089dup p.S364Qfs*33 (on ENST00000427332; = p.S403Qfs*33 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/96 reads (35%) | catalogued as rs750203996; called by mutect2, pindel, varscan2
- HDLBP | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100191158, COSV60499427; called by muse, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs771658394; called by mutect2, varscan2
- HECTD4 | c.10061G>A p.R3354H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66396907, COSV66399461; called by muse, mutect2, varscan2
- HEG1 | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1455668998, COSV60764377; called by muse, mutect2
- HERC1 | c.1796C>G p.T599S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV71249494; called by muse, varscan2
- HHIP | c.1158-2A>G p.X386_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as COSV56842700; called by muse, mutect2, varscan2
- HIC2 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV68042687; called by muse, mutect2, varscan2
- HIPK4 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs756252191, COSV52524404; called by muse, mutect2, varscan2
- HIVEP1 | c.2812A>G p.K938E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV65103912; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 42/229 reads (18%) | catalogued as rs199474609; called by mutect2, varscan2
- HLA-B | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV69520249; called by muse, varscan2
- HLA-C | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs281860390, COSV66117254; called by muse, mutect2, varscan2
- HLA-E | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs751016907, COSV64927768; called by muse, mutect2, varscan2
- HLA-F | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs763378037, COSV52576790; called by muse, mutect2, varscan2
- HLTF | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs770061848, COSV59500676, COSV59502607; called by muse, mutect2, varscan2
- HMCN1 | c.13883A>G p.N4628S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV54926341; called by muse, mutect2
- HNRNPAB | c.843_860del p.Y282_G287del | In Frame Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs754641334; called by mutect2, varscan2
- HNRNPUL1 | c.2570A>G p.*857Wext*3 | Nonstop Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV54191304; called by muse, mutect2, varscan2
- HOXB1 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as COSV53318260; called by muse, mutect2, varscan2
- HRC | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53258066; called by muse, mutect2, varscan2
- HS2ST1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs865888400, COSV63352001; called by muse, mutect2, varscan2
- HS3ST2 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54466434; called by muse, mutect2, varscan2
- HSD3B7 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376746447, COSV52680466; called by muse, mutect2, varscan2
- HSP90AA1 | c.1966_1968del p.D656del | In Frame Del (DEL) | VAF 33/155 reads (21%) | catalogued as rs1322678444; called by mutect2, pindel, varscan2
- HSPA12B | c.42C>T p.I14= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as rs967610282, COSV54765957, COSV54768534; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR3A | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55470889; called by muse, mutect2, varscan2
- HUWE1 | c.11669A>G p.H3890R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53358253; called by muse, mutect2, varscan2
- ICOS | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57030673; called by muse, mutect2, varscan2
- IDH3G | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54209302; called by muse, mutect2, varscan2
- IFIT3 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV51080127; called by muse, mutect2, varscan2
- IGHM | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs782090515; called by muse, mutect2, varscan2
- IGHV4-28 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.139); catalogued as rs374397013; called by muse, varscan2
- IGKV3-7 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1282927500; called by muse, mutect2
- IGSF11 | c.1210T>C p.Y404H (on ENST00000393775 / NM_001015887.3; = p.Y403H on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV61175585; called by muse, mutect2, varscan2
- IHO1 | c.1732A>G p.K578E | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV56509281; called by muse, mutect2, varscan2
- IL17RB | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV55473911; called by muse, varscan2
- IL31 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as rs371405302; called by muse, mutect2, varscan2
- ILKAP | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54518830; called by muse, mutect2, varscan2
- IMPACT | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52422914; called by muse, mutect2, varscan2
- INHBA | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs376794102, COSV54220489, COSV99637640; called by muse, mutect2, varscan2
- INHBB | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1475923662, COSV54678836; called by muse, mutect2, varscan2
- INPP4A | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs1559033620, COSV50811540, COSV99302166; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSIG2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs750935813, COSV55523280; called by muse, mutect2, varscan2
- INTS11 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs572639895, COSV60089738; called by muse, mutect2, varscan2
- IPO9 | c.246A>C p.K82N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64234970; called by muse, mutect2, varscan2
- IQCC | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52210496; called by muse, mutect2, varscan2
- IQSEC1 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs751161861, COSV56227330; called by muse, mutect2, varscan2
- IRAK3 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | catalogued as COSV54164331; called by muse, mutect2, varscan2
- IRX2 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.247); catalogued as rs1384459544, COSV57412848; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- ISOC2 | c.487G>T p.G163W (on ENST00000425675 / NM_001136201.2; = p.G179W on NM_024710.3) | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV50035263; called by muse, mutect2, varscan2
- ITGAX | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51649230; called by muse, mutect2, varscan2
- ITGB8 | c.2192A>G p.K731R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.813); catalogued as COSV56012166; called by muse, mutect2, varscan2
- ITIH3 | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV69649789; called by muse, mutect2, varscan2
- JAG1 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54760879; called by muse, mutect2, varscan2
- JAKMIP3 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.24); catalogued as COSV53827316; called by muse, mutect2
- JMJD1C | c.4559G>A p.S1520N | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV59517101; called by muse, mutect2, varscan2
- KALRN | c.8701del p.H2901Mfs*7 (on ENST00000360013 / NM_001024660.4; = p.H1204Mfs*7 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs1559891628; called by mutect2, pindel, varscan2
- KANSL1L | c.2918A>T p.Y973F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.877); catalogued as COSV55995286; called by muse, mutect2, varscan2
- KAT6B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs568525923, COSV54741444; called by muse, mutect2, varscan2
- KAT6B | c.5279C>T p.P1760L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1385883942, COSV54752124; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNC4 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs764851791, COSV63926291; called by muse, mutect2, varscan2
- KCND3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557767012, COSV56186470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2, varscan2
- KCNJ5 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57969254; called by muse, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNT1 | c.2671C>T p.R891W (on ENST00000488444; = p.R910W on NM_020822.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249219901, COSV53707370; called by muse, varscan2
- KDF1 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs894118968, COSV57671016; called by muse, mutect2, varscan2
- KDM2B | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV100997309, COSV65643635; called by muse, mutect2, varscan2
- KDM4B | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50242830; called by muse, mutect2, varscan2
- KDM4B | c.2755G>A p.V919M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs762143895, COSV50242939; called by muse, mutect2, varscan2
- KDM5B | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1469607111, COSV52511018; called by muse, mutect2, varscan2
- KDM5C | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62891329; called by muse, mutect2, varscan2
- KHDRBS2 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55478477, COSV55487974; called by muse, mutect2, varscan2
- KIAA1109 | c.8446+2T>C p.X2816_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52686077; called by muse, mutect2, varscan2
- KIAA1549 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs750757143, COSV54323235; called by muse, mutect2
- KIAA1958 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61726516; called by muse, mutect2, varscan2
- KIAA1958 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV61726526; called by muse, mutect2, varscan2
- KIF16B | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as rs144734414; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF4B | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs778448313, COSV70530687; called by muse, mutect2, varscan2
- KIF5B | c.1864dup p.M622Nfs*5 | Frame Shift Ins (INS) | VAF 28/81 reads (35%) | catalogued as rs777526028; called by mutect2, varscan2
- KIF7 | c.1640del p.G547Afs*5 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs770571299, CX113624; called by mutect2, pindel
- KL | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66309593; called by muse, mutect2, varscan2
- KLF7 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV58745652; called by muse, mutect2, varscan2
- KLHL14 | c.1717T>C p.Y573H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV63834539; called by muse, mutect2, varscan2
- KLHL28 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs770354783, COSV61888247; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 92/193 reads (48%) | catalogued as rs749194179; called by mutect2, varscan2
- KLRG2 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV61801356; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as COSV55868319; called by mutect2, varscan2
- KRT27 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV56972287; called by muse, mutect2, varscan2
- KRT39 | c.1315T>G p.S439A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV62917784; called by muse, mutect2, varscan2
- KRT9 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV55852686; called by muse, mutect2
- KRTAP12-2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as COSV59973406; called by muse, mutect2, varscan2
- LARP4 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV53325563; called by muse, mutect2, varscan2
- LCT | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1287547378, COSV51553815; called by muse, mutect2, varscan2
- LDLR | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as rs1299591218, COSV52945102; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LETM1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs144099418; called by muse, mutect2, varscan2
- LGALS2 | c.254_255del p.T85Sfs*4 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs755573884; called by pindel, varscan2
- LGR4 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64865611; called by muse, mutect2, varscan2
- LGR6 | c.2405C>A p.P802H (on ENST00000367278 / NM_001017403.1; = p.P750H on NM_021636.3) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.926); catalogued as COSV55155752; called by muse, mutect2, varscan2
- LHFPL6 | c.139T>C p.F47L | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65447805; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LHX2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65317730; called by muse, mutect2
- LIG4 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs187323251; called by muse, mutect2, varscan2
- LILRA4 | c.1424del p.P475Qfs*69 | Frame Shift Del (DEL) | VAF 17/131 reads (13%) | catalogued as rs758325116, COSV52491499; called by mutect2, pindel, varscan2
- LINC02210-CRHR1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755641187, COSV53283480; called by muse, mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs1443101323; called by mutect2, pindel, varscan2
- LOXL4 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372637990; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LPL | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs377128614; called by muse, mutect2, varscan2
- LPO | c.1863G>T p.R621S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV99229165; called by muse, mutect2
- LPP | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767518342, COSV57081731; called by muse, mutect2, varscan2
- LRBA | c.4898G>A p.G1633D | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV63960942; called by muse, mutect2, varscan2
- LRP1 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV54520453; called by muse, mutect2, varscan2
- LRP1 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV54520468; called by muse, mutect2, varscan2
- LRP1 | c.11095C>T p.R3699W | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520484; called by muse, mutect2, varscan2
- LRRC4C | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749582918, COSV53433803; called by muse, mutect2, varscan2
- LRRC66 | c.1223dup p.C409Vfs*20 | Frame Shift Ins (INS) | VAF 18/30 reads (60%) | catalogued as rs752924856; called by mutect2, varscan2
- LRRIQ3 | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV63047887; called by muse, mutect2, varscan2
- LRRK1 | c.5771G>A p.R1924H | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1472884841, COSV52602772; called by muse, varscan2
- LRRK2 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772964685, COSV54164107; called by muse, mutect2, varscan2
- LTBP3 | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1372139167, COSV54214474; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs1460451498; called by mutect2, pindel, varscan2
- MACROD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs557866799, COSV54026962; called by muse, mutect2, varscan2
- MAG | c.1519+2T>C p.X507_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV62702130; called by muse, mutect2, varscan2
- MAGEB18 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57464460; called by muse, mutect2, varscan2
- MAGEC2 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV56000807; called by muse, mutect2
- MAGEC3 | c.1607G>T p.S536I | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as COSV68924108; called by muse, mutect2, varscan2
- MAGED2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs763271575, COSV54498872; called by muse, mutect2, varscan2
- MAGEE1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV63911533; called by muse, mutect2, varscan2
- MAN2B2 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53455612; called by muse, mutect2
- MAP1B | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs140205740; called by muse, mutect2, varscan2
- MAP7D3 | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100286554; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV50503169; called by muse, mutect2, varscan2
- MAPT | c.1964C>A p.T655N (on ENST00000262410 / NM_001377265.1; = p.T263N on NM_005910.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52245280; called by muse, mutect2, varscan2
- MARCHF10 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs202126080; called by muse, mutect2
- MARVELD2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs143318841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MATK | c.869G>A p.R290H (on ENST00000310132 / NM_139355.3; = p.R291H on NM_002378.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs374718615, COSV59555021, COSV59556063; called by muse, varscan2
- MBD3 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50084969; called by muse, mutect2, varscan2
- MCF2L | c.718A>G p.M240V (on ENST00000375608; = p.M208V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65050357; called by muse, mutect2, varscan2
- MED12L | c.5651A>G p.K1884R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.973); catalogued as COSV56390509, COSV99851390; called by muse, mutect2, varscan2
- MED13L | c.4397G>A p.R1466H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs140136426; called by muse, mutect2, varscan2
- MED15 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.78); PolyPhen probably damaging (0.954); catalogued as COSV99487976; called by muse, mutect2, varscan2
- MED15 | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.991); catalogued as COSV99487978; called by muse, mutect2, varscan2
- MED24 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs748099423, COSV56641716; called by muse, mutect2
- MED6 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56450782, COSV56450836; called by muse, mutect2, varscan2
- MEDAG | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV66850182, COSV66850654; called by muse, varscan2
- MEGF9 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1264177082, COSV64235035; called by muse, mutect2, varscan2
- MEP1A | c.1118A>C p.K373T | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.876); catalogued as COSV57921862; called by muse, mutect2, varscan2
- MEPCE | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1388171436, COSV52769716; called by muse, mutect2, varscan2
- METTL25 | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV50260740; called by muse, mutect2, varscan2
- MGAM | c.5243del p.G1748Afs*35 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs765764785; called by mutect2, pindel, varscan2
- MGAT5B | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56934041; called by muse, mutect2, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MICAL2 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV56320326; called by muse, mutect2, varscan2
- MICB | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.99); catalogued as COSV52857384; called by muse, mutect2, varscan2
- MIDEAS | c.89del p.P30Lfs*12 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as COSV99678615; called by mutect2, pindel, varscan2
- MIDN | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56296307; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINDY2 | c.1847del p.N616Ifs*41 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs1282883369; called by mutect2, pindel, varscan2
- MISP | c.1950G>T p.E650D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs571362658, COSV53121633; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP12 | c.1139T>A p.I380N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58258963, COSV58260802; called by muse, mutect2, varscan2
- MMP15 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV54679500, COSV54679758; called by muse, mutect2, varscan2
- MMP21 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100916690, COSV64289987; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MRC2 | c.3742+2T>C p.X1248_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV57642864; called by muse, mutect2, varscan2
- MRPS31 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs557779396, COSV60268033; called by muse, mutect2, varscan2
- MTDH | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs754496543, COSV60345820; called by muse, mutect2, varscan2
- MTF2 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.222); catalogued as COSV64771732; called by muse, mutect2, varscan2
- MTM1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368335697, COSV100080685, COSV60336753; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MTMR1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV60935762; called by muse, mutect2, varscan2
- MUC16 | c.18101A>G p.Q6034R | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV67481994; called by muse, mutect2, varscan2
- MUC17 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV60298171; called by muse, mutect2, varscan2
- MUC17 | c.6161C>T p.T2054M | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs140147544; called by muse, mutect2, varscan2
- MUC5AC | c.14809T>C p.Y4937H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611544; called by muse, mutect2, varscan2
- MYH1 | c.2666del p.N889Mfs*24 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs776259351; called by mutect2, pindel, varscan2
- MYH15 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1317895575, CM1513509, COSV56316216; called by muse, mutect2, varscan2
- MYH2 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV55444752; called by muse, mutect2, varscan2
- MYH6 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV62453133; called by muse, mutect2, varscan2
- MYLK2 | c.116del p.P39Qfs*12 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs1568626488, COSV101044743; called by mutect2, varscan2
- MYO1C | c.184G>A p.A62T (on ENST00000648651 / NM_001080779.2; = p.A27T on NM_033375.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs760702315, COSV63000251; called by muse, mutect2, varscan2
- MYOG | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54096298; called by muse, mutect2, varscan2
- MYOT | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51800150; called by muse, mutect2, varscan2
- MYRIP | c.2504C>A p.T835K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56877403; called by muse, mutect2, varscan2
- MZF1 | c.2144G>A p.G715D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV53042714; called by muse, mutect2, varscan2
- NAT16 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs750804809, COSV55865349; called by muse, mutect2, varscan2
- NAV2 | c.6430G>A p.V2144I (on ENST00000396087 / NM_001244963.2; = p.V2085I on NM_145117.5) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs750404096, COSV60662920; called by muse, mutect2, varscan2
- NAV2 | c.7150C>T p.R2384C (on ENST00000396087 / NM_001244963.2; = p.R2325C on NM_145117.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768870826, COSV60663084; called by muse, mutect2
- NCAM1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs782428703, COSV57510729; called by muse, mutect2, varscan2
- NCAPG | c.2236G>A p.V746I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs890096224, COSV52271946; called by muse, mutect2, varscan2
- NCKAP5 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as rs764177546, COSV58464126; called by muse, mutect2, varscan2
- NCOR2 | c.1982A>G p.N661S | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV62301851; called by muse, mutect2, varscan2
- NDFIP2 | c.941A>T p.Y314F | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529395; called by muse, mutect2
- NEB | c.7766A>G p.Y2589C | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51443236; called by muse, mutect2
- NEDD4L | c.1225C>T p.R409* (on ENST00000400345 / NM_001144967.3; = p.R389* on NM_015277.6) | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV56850123; called by muse, mutect2, varscan2
- NELL2 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61582094; called by muse, mutect2, varscan2
- NEMF | c.806+1G>A p.X269_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV53594045; called by muse, mutect2, varscan2
- NES | c.906C>T p.Y302= | Splice Region (SNP) | VAF 15/70 reads (21%) | catalogued as rs776441024, COSV63960703, COSV63962260; called by muse, mutect2, varscan2
- NETO1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs574511728, COSV55001768, COSV55002830; called by muse, mutect2, varscan2
- NEU1 | c.517T>C p.W173R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV57668605; called by muse, mutect2, varscan2
- NEUROG1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772487296, COSV59082884; called by muse, mutect2, varscan2
- NGF | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV65688511; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIBAN2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs527792182, COSV64825167; called by muse, mutect2, varscan2
- NIT2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777950856, COSV67630631; called by muse, mutect2, varscan2
- NKAIN2 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV63680294; called by muse, mutect2, varscan2
- NKAP | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65056730; called by muse, mutect2, varscan2
- NKX6-1 | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV55685455, COSV99879868; called by muse, mutect2, varscan2
- NLGN4X | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV52030170; called by muse, mutect2, varscan2
- NLRP12 | c.2939G>T p.C980F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60751974; called by muse, mutect2, varscan2
- NLRP9 | c.2129A>G p.K710R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV60466282; called by muse, mutect2, varscan2
- NLRX1 | c.1887del p.L630Ffs*10 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as rs749769992; called by mutect2, pindel, varscan2
- NME6 | c.428C>T p.A143V (on ENST00000415053; = p.A151V on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as COSV56640896; called by muse, mutect2, varscan2
- NMUR2 | c.726+2T>C p.X242_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99677168; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs746543323; called by mutect2, varscan2
- NOSTRIN | c.1220del p.L407* (on ENST00000317647 / NM_001039724.4; = p.L329* on NM_052946.3) | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs1258179126; called by mutect2, pindel, varscan2
- NOTCH1 | c.6920A>G p.Q2307R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.11); catalogued as COSV53077025; called by muse, mutect2, varscan2
- NPAP1 | c.1900A>G p.S634G | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61508397, COSV61512207, COSV99051844; called by muse, mutect2, varscan2
- NPAS2 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.406); catalogued as rs761426802, COSV59560654; called by muse, mutect2, varscan2
- NPTXR | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs764050642, COSV60727856; called by muse, mutect2, varscan2
- NRDC | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773828082, COSV61407117; called by muse, mutect2, varscan2
- NRG1 | c.230G>A p.R77Q (on ENST00000523534; = p.R224Q on NM_013962.2) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs1021029930, COSV73064597; called by muse, varscan2
- NRK | c.4583G>T p.R1528M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV54602968; called by muse, mutect2, varscan2
- NRSN2 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV66526917; called by muse, mutect2, varscan2
- NRXN2 | c.3961C>A p.L1321M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV55460305; called by muse, mutect2, varscan2
- NRXN2 | c.3734C>T p.P1245L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55450049; called by muse, mutect2, varscan2
- NRXN3 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.067); catalogued as COSV99820755; called by muse, mutect2, varscan2
- NT5C1B | c.812A>G p.Q271R (on ENST00000359846 / NM_001199086.2; = p.Q211R on NM_033253.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1220882668, COSV100409964, COSV58397955; called by muse, mutect2, varscan2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as rs754390000; called by mutect2, pindel, varscan2
- NUAK1 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs768722408, COSV54606523; called by muse, mutect2, varscan2
- NUDT1 | c.320A>G p.H107R (on ENST00000397048 / NM_198952.1; = p.H84R on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56129058; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 42/170 reads (25%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUMA1 | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV61189094; called by muse, mutect2, varscan2
- NUP210 | c.4952C>T p.T1651M | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1373092454, COSV54410917; called by muse, mutect2, varscan2
- NUP50 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs750750184, COSV61661399; called by muse, mutect2, varscan2
- NUP88 | c.2066A>G p.Q689R | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV99336896; called by muse, mutect2
- NUP98 | c.5324C>A p.P1775H (on ENST00000359171 / NM_001365126.1; = p.P1758H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.315); catalogued as COSV51710045; called by muse, mutect2, varscan2
- NUTM2A | c.2393A>G p.H798R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.097); catalogued as rs1184800126, COSV67742092; called by mutect2, varscan2
- OBSCN | c.18391A>G p.I6131V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV52808306; called by muse, mutect2, varscan2
- OBSCN | c.19933G>A p.D6645N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759460387, COSV63016638; called by muse, mutect2, varscan2
- OPCML | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1316485986, COSV59440472; called by muse, mutect2, varscan2
- OPLAH | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV70678859; called by muse, mutect2, varscan2
- OPTC | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs746898636, COSV65867269, COSV65868337; called by muse, mutect2, varscan2
- OR10H1 | c.388del p.L130Cfs*7 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs774838264; called by mutect2, varscan2
- OR10P1 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as rs776836457, COSV59008192; called by muse, mutect2, varscan2
- OR10R2 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63769288; called by muse, mutect2, varscan2
- OR12D3 | c.577A>G p.N193D | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65829529; called by muse, varscan2
- OR1F1 | c.471_473del p.L158del | In Frame Del (DEL) | VAF 36/142 reads (25%) | catalogued as rs200396618; called by mutect2, pindel, varscan2
- OR2D3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs767728926, COSV53492929, COSV99549752; called by muse, mutect2, varscan2
- OR2F2 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as COSV68833167; called by muse, mutect2
- OR2K2 | c.335T>C p.V112A (on ENST00000374428; = p.V83A on NM_205859.2) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57017924; called by muse, mutect2, varscan2
- OR2T11 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58186710, COSV58187385; called by muse, mutect2, varscan2
- OR2T33 | c.189A>T p.Q63H | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV58816941; called by muse, varscan2
- OR4A15 | c.740T>A p.L247* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | catalogued as COSV59036712; called by muse, mutect2
- OR4N5 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs143406902; called by muse, mutect2, varscan2
- OR5V1 | c.479_480del p.T160Sfs*15 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs779710209; called by mutect2, pindel, varscan2
- OR6K3 | c.88T>A p.F30I (on ENST00000368146; = p.F14I on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV63746189; called by muse, mutect2
- OR7C1 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV50183983; called by muse, mutect2, varscan2
- OR8K5 | c.870C>G p.Y290* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as rs751205072, COSV57890305, COSV57891867; called by muse, mutect2
- OR8S1 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1488281938, COSV59600446; called by muse, mutect2, varscan2
- ORC1 | c.2422A>C p.M808L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65364755; called by muse, mutect2, varscan2
- OTUD7A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100192955; called by muse, mutect2, varscan2
- OVCH1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.101); catalogued as COSV58966463; called by muse, mutect2, varscan2
- OVCH1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58966474; called by muse, mutect2, varscan2
- OXCT2 | c.970del p.L324Cfs*11 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs1200902417; called by mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs763394045; called by mutect2, varscan2
- PACS2 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as rs782607135, COSV57651437; called by muse, mutect2, varscan2
- PAM | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs1233318771, COSV57212788; called by muse, mutect2
- PARP10 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100478478, COSV57299439; called by muse, mutect2, varscan2
- PARP14 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.24); catalogued as COSV72111738; called by muse, mutect2, varscan2
- PAX6 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1331716310, COSV53794985; called by muse, mutect2, varscan2
- PBX4 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs376647012; called by muse, mutect2, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, mutect2, varscan2
- PCDH17 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64971905; called by muse, mutect2, varscan2
- PCDH8 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV58814346; called by muse, mutect2, varscan2
- PCDHAC1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs1554204518, COSV53853503; called by muse, mutect2, varscan2
- PCDHAC2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV53863084; called by muse, mutect2, varscan2
- PCDHAC2 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as rs1404110882, COSV53863093; called by muse, mutect2, varscan2
- PCDHB3 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs782736232, COSV50606885, COSV99166133; called by muse, mutect2, varscan2
- PCDHGB6 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV53942275; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 70/227 reads (31%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCGF2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs751218338; called by muse, varscan2
- PCID2 | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV55814608; called by muse, mutect2, varscan2
- PCK1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs200991428, COSV60126462; called by muse, mutect2, varscan2
1,134 further variants in this file (727 protein-altering or splice-affecting, 362 silent, 45 other) are not listed here.
